TCGA case TCGA-B5-A3FH — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/139e2c5a-cc0c-43a2-b30e-b8ac17c0b5f2

Demographics
Sex at birth: female; Race: black or african american; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 74.5 years (27,221 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; FIGO stage: Stage IA; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 841 days (2.3 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 6.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 17.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 9.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 197 days; Disease response: Tumor Free.
- Days to follow up: 434 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 841 days (2.3 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 160 cm; BMI: 33.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B5-A3FH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 480 mg.
  Slide TCGA-B5-A3FH-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 2.
- Sample TCGA-B5-A3FH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B5-A3FH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form 1: Lost to follow-up: No; History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Pregnancies full term count: 3; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 3; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 841 days; disease-specific survival: no event (censored), 841 days; disease-free interval: no event (censored), 841 days; progression-free interval: no event (censored), 841 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B5-A3FH-01A-11D-A19X-01): tumor purity 0.81, ploidy 2.07, whole-genome doublings 0.
